Gene-level copy-number profile of tumor specimen TCGA-TS-A7OZ-01A from TCGA case TCGA-TS-A7OZ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-TS-A7OZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-MESO.b1f5010a-3755-4b75-acf0-36b3de3bb95c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TS-A7OZ-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f42602d2-57ff-4751-9599-e8c37758b67a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 15,816; copy number 2: 42,153; copy number 3: 1,784.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-TS-A7OZ-01A-21D-A39Q-01): tumor purity 0.56, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 61 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:68,004,247–68,637,024, 6 genes: TAFA1, COPS8P2, AC107626.1, AC104167.1, AC096922.1, PSMC1P1.
- chr4:156,006,478–156,006,988, 1 gene: FTH1P21.
- chr4:157,204,182–157,366,075, 1 gene (within-gene range 0–1): GRIA2.
- chr4:157,568,731–157,962,924, 7 genes: AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5.
- chr4:157,945,817–157,969,615, 2 genes: AC017037.4, AC017037.2.
- chr9:21,384,255–22,824,213, 33 genes: IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr11:112,822,806–113,400,416, 9 genes: AC016902.1, AP000802.1, NCAM1, RNU7-187P, NCAM1-AS1, AP000880.1, TTC12, AP002840.2, ANKK1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 13,430. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
